Somatic mutation profile of tumor specimen 0DAOC0 from CCDI case PBBKHG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,719 days).
Specimen 0DAOC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b861558-9815-4846-8f99-3d200db8fa4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOC1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d079641-bc69-4d5a-8d10-e08e4c90ea96

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 602/950 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 401/529 reads (76%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 555/628 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC168 | c.3332A>G p.N1111S | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs948783625; called by muse, mutect2, varscan2
- FAM78B | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 136/928 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); catalogued as rs1307924765; called by muse, mutect2, varscan2
- GLIS1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 408/863 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV56548365; called by muse, mutect2, varscan2
- GPR146 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 131/724 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV52465815; called by muse, mutect2, varscan2
- RAD21L1 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs1306454661, COSV67881730; called by muse, mutect2, varscan2
- RIOK3 | c.1075A>C p.M359L | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs759593902; called by muse, mutect2, varscan2
- WDR64 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 104/861 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as rs536501700, COSV63794724, COSV63798995; called by muse, mutect2, varscan2
- ZNF563 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 105/627 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.21); catalogued as COSV53369609; called by muse, mutect2, varscan2
- AXDND1 | c.2732A>G p.Q911R | Missense Mutation (SNP) | VAF 65/545 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DUXA | c.288T>G p.F96L | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- FEM1C | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- MCM5 | c.2074C>G p.H692D | Missense Mutation (SNP) | VAF 110/603 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- POTEF | c.1596G>T p.E532D | Missense Mutation (SNP) | VAF 313/909 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SLC10A4 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 89/944 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTBN4 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 90/463 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNFRSF11B | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 59/482 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ADCK5 | c.1149C>T p.H383= | Silent (SNP) | VAF 129/930 reads (14%) | catalogued as rs782536387; called by muse, mutect2, varscan2
- DCUN1D4 | c.429C>G p.V143= | Silent (SNP) | VAF 519/1006 reads (52%) | called by muse, varscan2
- GATA3 | c.1059C>A p.P353= | Silent (SNP) | VAF 214/452 reads (47%) | catalogued as rs756535371; called by muse, mutect2, varscan2
- HEXIM2 | c.651C>T p.Y217= | Silent (SNP) | VAF 134/703 reads (19%) | called by muse, mutect2, varscan2
- OR2T1 | c.582C>T p.Y194= | Silent (SNP) | VAF 96/889 reads (11%) | catalogued as rs148427102; called by muse, mutect2, varscan2
- RB1CC1 | c.315T>A p.S105= | Silent (SNP) | VAF 280/403 reads (69%) | called by muse, mutect2, varscan2
- SH3BP5L | c.984C>T p.P328= | Silent (SNP) | VAF 96/1196 reads (8%) | catalogued as rs762518138, COSV63539306; called by muse, mutect2
- HOXC8 | c.*63A>G | 3'UTR (SNP) | VAF 146/254 reads (57%) | called by mutect2, varscan2
- KCNK17 | c.514-43G>A | Intron (SNP) | VAF 107/278 reads (38%) | catalogued as rs754924644; called by muse, mutect2, varscan2
- TFAP2B | c.*63A>T | 3'UTR (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.10361-5600G>A | Intron (SNP) | VAF 65/592 reads (11%) | called by muse, mutect2, varscan2
